Somatic mutation profile of tumor specimen 0DXAR1 from CCDI case PBCRFZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Pineal gland; Age at diagnosis: 1.6 years (585 days).
Specimen 0DXAR1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc1fa79-e7ac-450e-9155-3ed522a05101.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXAQH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af757f30-f682-479a-8dba-0d797ca03fff

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ILKAP | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54520407; called by muse, mutect2, varscan2
- SMARCB1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 340/374 reads (91%) | catalogued as CM034687, COSV54096035, COSV54099986; called by muse, mutect2, varscan2
- TMPRSS6 | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- ZBED9 | c.651T>C p.I217= | Silent (SNP) | VAF 95/329 reads (29%) | called by muse, mutect2, varscan2
